Somatic mutation profile of tumor specimen TCGA-AB-2806-03B (aliquot TCGA-AB-2806-03B-01W-0728-08) from TCGA case TCGA-AB-2806, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.2 years (16,892 days).
Specimen TCGA-AB-2806-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0512b3a1-9954-46a8-8a43-66e9fa1b7657.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2806-11B (Solid Tissue Normal), aliquot TCGA-AB-2806-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06522f6c-ebca-4019-b445-c3c2c2719c78

The open-access MAF lists 572 somatic variants for this specimen: 428 protein-altering or splice-affecting, 127 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 356, Silent 127, Nonsense Mutation 29, Frame Shift Ins 20, Frame Shift Del 14, Intron 13, Splice Site 5, Splice Region 2, 5'Flank 2, In Frame Ins 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs377247120; called by muse, mutect2
- AARS1 | c.1346A>T p.Q449L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99933769; called by muse, mutect2, varscan2
- ABHD2 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs1330757158, COSV100756447; called by muse, mutect2
- ACP7 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100488598; called by muse, mutect2
- ADAM12 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901393; called by muse, mutect2
- ADAM19 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 12/150 reads (8%) | catalogued as COSV57427667; called by muse, mutect2
- ADAMTSL1 | c.4939G>C p.E1647Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as COSV101000906; called by muse, mutect2
- ADSS1 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV100272421; called by muse, mutect2, varscan2
- ADSS2 | c.1246A>T p.R416W | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100836902; called by muse, mutect2
- AFF1 | c.2899C>A p.H967N | Missense Mutation (SNP) | VAF 21/355 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); catalogued as COSV100321020, COSV57118454; called by muse, mutect2
- AGGF1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100462199; called by muse, mutect2
- AHNAK | c.11933A>G p.E3978G | Missense Mutation (SNP) | VAF 99/444 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV99949392; called by muse, mutect2, varscan2
- AHNAK | c.3172C>T p.P1058S | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1263486868, COSV99949394; called by muse, mutect2
- AKAP6 | c.3893A>T p.E1298V | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV99804131; called by muse, mutect2
- ALAS1 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100050468; called by muse, mutect2
- ALAS2 | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV100238600; called by muse, mutect2
- ALKBH1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.09); catalogued as COSV53174022, COSV99380762; called by muse, mutect2
- ALPK2 | c.1292T>A p.L431H | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100864767; called by muse, mutect2
- ALPK3 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV51933726; called by muse, mutect2
- AMELX | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV100499039; called by muse, varscan2
- AMER1 | c.2431A>G p.I811V | Missense Mutation (SNP) | VAF 190/331 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.159); catalogued as COSV100366978; called by muse, mutect2, varscan2
- ANKRD27 | c.1262A>G p.D421G | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100043131; called by muse, mutect2
- ANKZF1 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 32/347 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55477103; called by muse, mutect2, varscan2
- AP3B2 | c.3149T>C p.L1050P (on ENST00000261722; = p.L1044P on NM_004644.5) | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99916971; called by muse, mutect2
- APOBEC3C | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 40/1452 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV99329171; called by muse, mutect2
- APOL1 | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100046355; called by muse, mutect2
- ARHGAP31 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV51793956; called by muse, mutect2
- ARHGAP32 | c.3776C>T p.A1259V (on ENST00000310343 / NM_001378025.1; = p.A910V on NM_014715.4) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs1169574099, COSV100089153; called by muse, mutect2, varscan2
- ARHGAP35 | c.3892C>T p.Q1298* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV101351621; called by mutect2, varscan2
- ATG2A | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751226427, COSV101033846; called by mutect2, varscan2
- ATM | c.8513A>T p.K2838I | Missense Mutation (SNP) | VAF 40/539 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99591711; called by muse, mutect2
- ATOH1 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100024572; called by muse, mutect2, varscan2
- ATP1B1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1002822395, COSV63179198; called by muse, mutect2
- ATRX | c.2080C>G p.P694A | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV64876626; called by muse, mutect2
- BPIFB3 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs989319740, COSV100972411; called by muse, mutect2
- C1QA | c.78C>G p.C26W | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101009965, COSV101009968, COSV101009970; called by muse, mutect2, varscan2
- C1orf56 | c.627G>A p.W209* | Nonsense Mutation (SNP) | VAF 7/102 reads (7%) | catalogued as COSV54847521; called by muse, mutect2
- C2orf80 | c.429A>T p.K143N | Missense Mutation (SNP) | VAF 25/853 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV100378622; called by muse, mutect2
- C9orf72 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1342517641, COSV101186558; called by muse, mutect2
- C9orf78 | c.810C>G p.N270K | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs147768922, COSV61028841; called by muse, mutect2, varscan2
- CA9 | c.194T>A p.L65Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV65676752; called by muse, mutect2
- CACNA1A | c.1847G>A p.S616N | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100803131; called by muse, mutect2
- CACNA1C | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 54/1188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100216608, COSV59713701; called by muse, mutect2
- CALCOCO1 | c.1312A>G p.K438E | Missense Mutation (SNP) | VAF 30/510 reads (6%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.76); catalogued as COSV100017469; called by muse, mutect2
- CASR | c.2891G>A p.R964Q (on ENST00000490131; = p.R1041Q on NM_000388.4) | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761580803, COSV56136442; ClinVar: uncertain significance; called by muse, mutect2
- CC2D1A | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as rs774058378; called by muse, mutect2, varscan2
- CC2D1A | c.1232dup p.I412Nfs*29 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | catalogued as rs766223636; called by mutect2, pindel
- CCDC40 | c.403del p.E135Rfs*32 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as COSV53901045; called by mutect2, pindel, varscan2
- CCDC42 | c.644T>A p.L215Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99549919; called by muse, mutect2
- CCL17 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1414060852, COSV99537221; called by muse, mutect2, varscan2
- CCNA1 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs139038414, COSV55223954; called by muse, mutect2, varscan2
- CD180 | c.509T>C p.F170S | Missense Mutation (SNP) | VAF 23/688 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99842375; called by muse, mutect2
- CDAN1 | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100661431; called by muse, varscan2
- CDAN1 | c.2007G>C p.Q669H | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100661432; called by muse, mutect2, varscan2
- CDC42BPA | c.5045C>T p.P1682L (on ENST00000334218 / NM_001366019.2; = p.P1669L on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV100506753; called by muse, mutect2
- CEACAM20 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100387022; called by muse, mutect2
- CEACAM5 | c.1874A>G p.Y625C | Missense Mutation (SNP) | VAF 92/464 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99704143; called by muse, varscan2
- CELF1 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100137205; called by muse, mutect2
- CELSR3 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779915965, COSV99374845; called by muse, mutect2, varscan2
- CEP250 | c.4364A>T p.K1455M | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.64); catalogued as COSV100699167; called by muse, mutect2
- CFTR | c.2654G>T p.G885V | Missense Mutation (SNP) | VAF 40/305 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV99139363; called by muse, mutect2, varscan2
- CLK3 | c.1471C>T p.P491S (on ENST00000395066 / NM_001130028.1; = p.P343S on NM_003992.4) | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100166152; called by muse, mutect2
- CMIP | c.1812G>T p.Q604H (on ENST00000537098 / NM_198390.2; = p.Q510H on NM_030629.3) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV101220959; called by muse, mutect2
- CNN1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 54/1426 reads (4%) | catalogued as COSV99372515; called by muse, mutect2
- COL6A3 | c.9424T>C p.Y3142H | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV55100418, COSV99801037; called by muse, mutect2
- COPS7A | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 16/347 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV99976570; called by muse, mutect2
- CREB3L1 | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV55830367; called by muse, mutect2
- CREB3L2 | c.1231A>T p.S411C | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100382268; called by muse, mutect2
- CSPG5 | c.1692T>A p.N564K (on ENST00000383738 / NM_001206943.2; = p.N537K on NM_006574.4) | Missense Mutation (SNP) | VAF 34/718 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99274138; called by muse, mutect2
- CST6 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376219; called by muse, mutect2, varscan2
- CSTF2 | c.1562G>A p.G521D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV100880878; called by muse, mutect2
- CYP19A1 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 27/220 reads (12%) | catalogued as rs72552260, CM004195, COSV53057103; called by muse, mutect2, varscan2
- DAAM1 | c.1648C>A p.P550T | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100658643; called by muse, mutect2
- DAO | c.959G>T p.W320L | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.292); catalogued as COSV99948859; called by muse, mutect2
- DDR2 | c.2321G>A p.G774E | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100906831; called by muse, mutect2
- DHX33 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as rs534212443, COSV99834503; called by muse, mutect2, varscan2
- DLGAP2 | c.2728G>A p.V910I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101422631; called by muse, mutect2
- DNAJC22 | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV101222600, COSV67712126, COSV67712547; called by muse, mutect2
- DNHD1 | c.11989C>T p.P3997S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV99600902; called by muse, mutect2, varscan2
- DNM1 | c.1482A>G p.I494M | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100360294; called by muse, mutect2
- DOP1B | c.2742C>A p.D914E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV101215797; called by muse, mutect2, varscan2
- DSG3 | c.1734G>A p.M578I | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99934688; called by muse, mutect2
- EDC4 | c.2894G>T p.R965L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs763409752, COSV100197771; called by mutect2, varscan2
- EDC4 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100197772; called by muse, mutect2, varscan2
- EFHC2 | c.1649T>C p.L550P | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100638043; called by muse, mutect2
- EGFLAM | c.2524G>A p.G842S (on ENST00000354891 / NM_001205301.2; = p.G834S on NM_152403.4) | Missense Mutation (SNP) | VAF 65/605 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs757552717, COSV100380729; called by muse, mutect2, varscan2
- ELP1 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV101010476; called by muse, mutect2
- ENOX1 | c.1413G>C p.Q471H | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99817030; called by muse, mutect2
- ENPP6 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 61/277 reads (22%) | catalogued as COSV57070954; called by muse, mutect2, varscan2
- EPHA4 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1429334984, COSV99917391; called by muse, mutect2, varscan2
- ERCC1 | c.601A>T p.S201C | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99185389; called by muse, mutect2, varscan2
- ESM1 | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.122); catalogued as COSV101195716, COSV67318511; called by muse, mutect2
- EZR | c.356dup p.E120* | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | catalogued as rs923993817; called by pindel, varscan2
- FAHD2B | c.710G>A p.C237Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738265; called by muse, mutect2, varscan2
- FARP2 | c.2212G>T p.E738* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99885484; called by muse, varscan2
- FAT2 | c.9835C>G p.L3279V | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363769217, COSV99944020; called by muse, mutect2
- FBXO11 | c.2430_2431insTC p.N811Sfs*3 (on ENST00000403359 / NM_001190274.2; = p.N727Sfs*3 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 60/150 reads (40%) | catalogued as COSV52277202; called by mutect2, pindel, varscan2
- FBXO6 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV65100395; called by muse, mutect2, varscan2
- FERD3L | c.305A>G p.Q102R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV99285073; called by mutect2, varscan2
- FGF13 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100264574; called by muse, mutect2
- FLG | c.11339G>T p.R3780M | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs367989347, COSV64242728; called by muse, mutect2
- FLRT2 | c.1825A>T p.I609F | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100420963; called by muse, mutect2
- FNBP4 | c.634G>T p.G212* | Nonsense Mutation (SNP) | VAF 20/358 reads (6%) | catalogued as COSV99771959; called by muse, mutect2
- FNBP4 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 31/839 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99771961; called by muse, mutect2
- FOCAD | c.4205A>G p.Q1402R | Missense Mutation (SNP) | VAF 68/868 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147846255; called by muse, mutect2
- FOXM1 | c.841T>C p.W281R | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700902; called by muse, mutect2, varscan2
- FREM2 | c.5411-2A>G p.X1804_splice | Splice Site (SNP) | VAF 8/128 reads (6%) | catalogued as COSV99750597; called by muse, mutect2
- G6PD | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 3/58 reads (5%) | catalogued as COSV100855124; called by muse, mutect2
- GALNTL5 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 15/188 reads (8%) | catalogued as COSV101218030, COSV67179543; called by muse, mutect2
- GFPT2 | c.1838G>C p.R613P | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99518051; called by muse, mutect2
- GHR | c.1573C>A p.Q525K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as COSV100051921; called by muse, mutect2
- GJA4 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV100654745; called by muse, mutect2, varscan2
- GJC1 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395234; called by muse, mutect2
- GLTP | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 37/406 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100570395; called by muse, mutect2
- GML | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.226); catalogued as COSV99638582; called by muse, mutect2, varscan2
- GNS | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99254011; called by muse, mutect2
- GON4L | c.5347C>T p.R1783W | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs778659875, COSV99675629; called by muse, mutect2, varscan2
- GPD2 | c.23A>G p.K8R | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100133638; called by muse, mutect2, varscan2
- GPR156 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | catalogued as COSV100251687; called by muse, mutect2, varscan2
- GRIN3A | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 90/721 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100701788, COSV62458149; called by muse, mutect2, varscan2
- HAT1 | c.185A>G p.D62G | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99908099; called by muse, mutect2
- HCN1 | c.2512C>A p.R838S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.982); catalogued as COSV100300365, COSV57503156, COSV57510575; called by muse, mutect2, varscan2
- HDAC4 | c.2614C>A p.P872T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614166; called by mutect2, varscan2
- HEATR5B | c.3509A>T p.H1170L | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV99248526, COSV99250149; called by muse, mutect2
- HEPHL1 | c.1586C>T p.T529I | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV100244361; called by muse, mutect2
- HJV | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV100382386; called by muse, mutect2, varscan2
- HMBS | c.84C>G p.S28R | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV99598168; called by muse, mutect2, varscan2
- HNRNPDL | c.682G>T p.G228W | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55023375, COSV99787209; called by muse, mutect2
- HNRNPH1 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV100270952, COSV61487742; called by muse, varscan2
- HSPG2 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV101012997; called by muse, mutect2
- IAH1 | c.512A>G p.Q171R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100176506; called by muse, varscan2
- IGF2 | c.656C>G p.T219S (on ENST00000434045 / NM_001127598.3; = p.T163S on NM_000612.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV100324217; called by muse, mutect2, varscan2
- IGHV3-23 | c.277A>T p.N93Y | Missense Mutation (SNP) | VAF 134/1856 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs572275669; called by muse, mutect2
- IL4R | c.2426C>T p.P809L | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV99405381; called by muse, mutect2
- INHBB | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.579); catalogued as COSV99736173; called by muse, mutect2, varscan2
- IP6K3 | c.1050G>C p.Q350H | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); catalogued as COSV99540134; called by muse, mutect2
- IQCC | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1322109680, COSV99356786; called by muse, mutect2
- IQCN | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101148997, COSV66578923; called by muse, varscan2
- ISX | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV100434177; called by muse, mutect2, varscan2
- ITIH6 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV99513906; called by muse, mutect2
- ITSN2 | c.5036C>G p.T1679S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.108); catalogued as COSV100744108; called by muse, mutect2, varscan2
- KAT6A | c.1898C>A p.S633Y | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99705803; called by muse, mutect2
- KCNA1 | c.1079C>G p.P360R | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101230345; called by muse, mutect2
- KCNIP2 | c.673C>T p.P225S (on ENST00000356640 / NM_173191.3; = p.P240S on NM_014591.5) | Missense Mutation (SNP) | VAF 22/672 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV99493588; called by muse, mutect2
- KDM6A | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65038913, COSV65040651; called by muse, mutect2, varscan2
- KIAA1210 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.118); catalogued as COSV68175903; called by muse, mutect2
- KIAA1217 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs368870981; called by muse, mutect2, varscan2
- KLHL5 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99785825; called by muse, mutect2, varscan2
- KMT2A | c.11171A>G p.H3724R | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100629741, COSV63292708; called by muse, mutect2
- KMT5C | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs1344078387, COSV99726239, COSV99726325; called by muse, mutect2, varscan2
- KRT4 | c.109G>T p.G37* | Nonsense Mutation (SNP) | VAF 23/181 reads (13%) | catalogued as COSV99543195; called by muse, mutect2, varscan2
- KRT79 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1274531789; called by muse, mutect2
- KRTAP10-11 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 30/636 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs1555940108, COSV100555358; called by muse, mutect2
- KRTAP10-5 | c.618G>C p.Q206H | Missense Mutation (SNP) | VAF 36/972 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100555356; called by muse, mutect2
- KRTAP9-3 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 17/309 reads (6%) | SIFT tolerated (0.88); catalogued as rs368191159; called by muse, mutect2
- KY | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101415032, COSV71016411; called by muse, mutect2
- L3MBTL1 | c.1070G>A p.R357H (on ENST00000418998 / NM_001377303.1; = p.R267H on NM_015478.7) | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376109118, COSV64228393; called by muse, mutect2, varscan2
- LAMC3 | c.2336_2337insT p.Q781Pfs*7 | Frame Shift Ins (INS) | VAF 3/33 reads (9%) | catalogued as COSV100736134; called by mutect2, pindel
- LARP4 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99529622; called by muse, mutect2
- LENG1 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.885); catalogued as COSV99652304; called by muse, mutect2, varscan2
- LENG9 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs151055628; called by muse, varscan2
- LINGO1 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV100796500, COSV62438032; called by muse, mutect2
- LTF | c.2038A>G p.K680E | Missense Mutation (SNP) | VAF 21/517 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as COSV99211311; called by muse, mutect2
- LYPLA2 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100994843; called by muse, mutect2, varscan2
- MAGEB16 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101303331; called by muse, mutect2
- MAGEB6B | c.320A>G p.Q107R | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.98); catalogued as rs1569250149; called by muse, mutect2
- MAP3K7 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100997555; called by muse, mutect2
- MAP7D2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs895915818, COSV101107535; called by muse, mutect2
- MAPK13 | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99275576; called by muse, mutect2
- MARS1 | c.997T>C p.C333R | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100007641; called by muse, mutect2
- MAST2 | c.4603C>G p.P1535A | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV99422821; called by muse, mutect2, varscan2
- MCRS1 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV99235729; called by muse, mutect2
- MEI1 | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 47/433 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV100300301; called by muse, mutect2, varscan2
- MEPCE | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV99440240; called by mutect2, varscan2
- MFAP3 | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); catalogued as COSV100491731; called by muse, mutect2
- MID2 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs182132222, COSV99465508; called by mutect2, varscan2
- MINDY4 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV54671471, COSV99519202; called by muse, mutect2
- MMP2 | c.664C>A p.R222S | Missense Mutation (SNP) | VAF 56/1007 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1215961278, COSV99528249; called by muse, mutect2
- MORC2 | c.677C>A p.A226E (on ENST00000397641 / NM_001303256.3; = p.A164E on NM_014941.3) | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99310382; called by muse, mutect2
- MRPL43 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV99273167; called by muse, varscan2
- MSH6 | c.2341C>A p.P781T | Missense Mutation (SNP) | VAF 59/875 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779235, COSV99314749, COSV99316827; ClinVar: uncertain significance; called by muse, mutect2
- MST1R | c.2512G>C p.V838L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV99619563, COSV99620122; called by muse, mutect2
- MST1R | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as COSV99619565; called by muse, mutect2
- MTMR1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1013831689, COSV100953152; called by muse, mutect2, varscan2
- MUC16 | c.39858G>C p.Q13286H | Missense Mutation (SNP) | VAF 56/2160 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.763); catalogued as COSV66691838; called by muse, mutect2
- MYD88 | c.871A>G p.K291E | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.455); catalogued as COSV100086425; called by muse, mutect2
- MYH10 | c.4417C>T p.R1473W | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs988699769, COSV99346213; called by muse, mutect2
- MYH13 | c.3469G>A p.A1157T | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99355334; called by muse, mutect2
- MYH6 | c.247A>G p.K83E | Missense Mutation (SNP) | VAF 48/489 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.674); catalogued as COSV100676963; called by muse, mutect2
- MYLK | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 32/818 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0.329); catalogued as COSV100659560; called by muse, mutect2
- NCOA3 | c.3145G>T p.D1049Y | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100508136; called by muse, mutect2
- NDRG2 | c.713A>T p.N238I (on ENST00000298687 / NM_001354570.1; = p.N224I on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100069148; called by muse, mutect2, varscan2
- NLGN2 | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV100081253; called by muse, mutect2
- NLRP14 | c.2710C>T p.H904Y | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100205402; called by muse, mutect2, varscan2
- NPAT | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV99586321; called by muse, varscan2
- NPC1 | c.3307G>A p.G1103S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs1317076046, COSV52571338; called by muse, mutect2, varscan2
- NRXN1 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs199548487, COSV58445112, COSV58479572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP210L | c.3368T>C p.V1123A | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55144515; called by muse, mutect2
- NUP214 | c.6034T>C p.F2012L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100845383; called by muse, mutect2
- NUP85 | c.1816G>T p.D606Y | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs761830415, COSV99822319; called by muse, mutect2
- OPRM1 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 131/225 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57674884; called by muse, mutect2, varscan2
- OR11H6 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV100209956; called by muse, mutect2
- OR4C15 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV58954251; called by muse, mutect2
- OR51B5 | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 9/294 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV56176524; called by muse, mutect2
- OR51L1 | c.513C>G p.C171W | Missense Mutation (SNP) | VAF 20/604 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100386481; called by muse, mutect2
- OR56B1 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 20/276 reads (7%) | catalogued as COSV100402537; called by muse, mutect2
- OR6F1 | c.82T>A p.F28I | Missense Mutation (SNP) | VAF 26/738 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100129437; called by muse, mutect2
- OR6N2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 43/1545 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1241425325, COSV59410931; called by muse, mutect2
- OR7D2 | c.853T>A p.L285M | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); catalogued as COSV60141190; called by muse, mutect2
- OR8D2 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 11/241 reads (5%) | catalogued as COSV100659095; called by muse, mutect2
- OR9G4 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100265256, COSV57248455; called by muse, mutect2
- OR9Q1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100110470; called by muse, mutect2
- OSBPL8 | c.1685G>T p.R562I | Missense Mutation (SNP) | VAF 50/648 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99675531; called by muse, mutect2
- OXER1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs751614026, COSV54312790, COSV99685539; called by mutect2, varscan2
- PAGR1 | c.617C>A p.S206* | Nonsense Mutation (SNP) | VAF 19/164 reads (12%) | catalogued as COSV100232780; called by muse, mutect2, varscan2
- PAK3 | c.508C>T p.P170S (on ENST00000262836 / NM_001324328.2; = p.P155S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53277838, COSV53280655; called by muse, mutect2
- PAPSS1 | c.1224A>T p.K408N | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV99492384; called by muse, mutect2
- PAPSS2 | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV100753672; called by muse, mutect2
- PCDHA4 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100793710; called by muse, mutect2
- PCDHB5 | c.2159C>A p.P720Q | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99169364, COSV99169424; called by muse, mutect2
- PCF11 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1233177746, COSV100019165; called by muse, mutect2
- PCYOX1L | c.185C>G p.T62S | Missense Mutation (SNP) | VAF 18/325 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.035); catalogued as COSV51004674, COSV99199276; called by muse, mutect2
- PDZD2 | c.4223G>A p.G1408D | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs764855194, COSV99226546; called by muse, mutect2, varscan2
- PDZD2 | c.4526C>A p.P1509H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223772; called by muse, mutect2, varscan2
- PGAM1 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100602460; called by muse, mutect2
- PGD | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV99581700; called by muse, mutect2, varscan2
- PHACTR3 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63025235, COSV63025385; called by muse, mutect2
- PKD2L1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 52/654 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs564442829, COSV100559338; called by muse, mutect2
- PKN1 | c.1220G>T p.W407L | Missense Mutation (SNP) | VAF 25/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54404897, COSV99661803; called by muse, mutect2
- PLCE1 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV53345427; called by muse, mutect2, varscan2
- PLD1 | c.3195G>T p.E1065D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100644050; called by muse, mutect2
- PLEKHA6 | c.1593+1G>T p.X531_splice | Splice Site (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99692684; called by muse, mutect2, varscan2
- PLEKHG1 | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100651865; called by muse, mutect2
- PLXNA2 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100885842; called by muse, mutect2
- PLXND1 | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as rs1039247005, COSV100140342; called by mutect2, varscan2
- PMF1 | c.404G>A p.S135N | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV100196397; called by muse, mutect2
- PNMA3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.453); catalogued as COSV100937666; called by muse, mutect2
- PNPLA3 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 20/553 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99337301; called by muse, mutect2
- POLE | c.5515C>A p.R1839S | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100268065; called by muse, mutect2
- PPIP5K1 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 33/671 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100613504; called by muse, mutect2
- PPP4R3A | c.1637C>G p.S546W (on ENST00000554943 / NM_001366432.1; = p.S533W on NM_001284280.1) | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100466817, COSV61504151, COSV61505250; called by muse, mutect2, varscan2
- PREB | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV99574800; called by muse, mutect2
- PROSER1 | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100613021; called by muse, mutect2
- PRPF8 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517861; called by muse, mutect2
- PRPS2 | c.877T>C p.S293P | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV101037739; called by muse, mutect2
- PSMD11 | c.810G>T p.L270F | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV99912620; called by muse, mutect2
- PSPC1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 36/982 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100142632; called by muse, mutect2
- PTPN14 | c.3161C>T p.T1054M | Missense Mutation (SNP) | VAF 64/454 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189546585; called by muse, mutect2, varscan2
- PTPRH | c.3221A>T p.Q1074L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99671421; called by muse, mutect2
- RAI1 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV99884945; called by muse, mutect2, varscan2
- RANBP6 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1404247317, COSV99424382; called by muse, mutect2
- RAPGEF2 | c.2911G>A p.A971T | Missense Mutation (SNP) | VAF 23/444 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV100031606; called by muse, mutect2
- RBM11 | c.743A>T p.K248M | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101271237; called by muse, mutect2, varscan2
- RGS1 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100817558; called by muse, mutect2
- RNF10 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100378965; called by muse, mutect2
- ROCK2 | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100255872; called by muse, mutect2, varscan2
- RPGRIP1L | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100046747; called by muse, mutect2
- RPL27 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99518551; called by muse, mutect2, varscan2
- RPS12 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100016389; called by muse, mutect2
- RPTN | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 46/1100 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV100285733; called by muse, mutect2
- RS1 | c.506A>G p.Q169R | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as COSV101183850; called by muse, mutect2
- RSAD2 | c.67T>A p.S23T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.037); catalogued as COSV101150024; called by muse, mutect2
- RSL1D1 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 26/1002 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100852011; called by muse, mutect2
- RTF1 | c.1724C>A p.S575Y | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101048184; called by muse, mutect2
- RTN4 | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100463887; called by muse, mutect2
- RUVBL2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV55487738; called by muse, mutect2, varscan2
- SCN1B | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 8/186 reads (4%) | catalogued as rs1555721396, COSV99385320; called by muse, mutect2
- SDK1 | c.3439C>T p.R1147* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as rs750313949, COSV67357896; called by muse, mutect2, varscan2
- SERPING1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV53543734; called by muse, mutect2
- SETD3 | c.1662C>G p.N554K | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV100075434, COSV59282428; called by muse, mutect2, varscan2
- SGCE | c.316G>A p.E106K (on ENST00000647096; = p.E70K on NM_003919.3) | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); catalogued as CM061976, COSV56016762; called by muse, mutect2
- SH3RF2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100768010; called by muse, mutect2
- SIN3A | c.2151G>C p.W717C | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845226; called by muse, mutect2
- SIN3B | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99932015; called by muse, mutect2, varscan2
- SIRT1 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99282023; called by muse, mutect2
- SIRT6 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99314466; called by muse, mutect2
- SLC26A9 | c.2212C>A p.Q738K | Missense Mutation (SNP) | VAF 50/597 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.057); catalogued as COSV100536743; called by muse, mutect2
- SLC28A1 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs781741336, COSV54476387; called by mutect2, varscan2
- SLC28A1 | c.1575G>C p.W525C | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99723485; called by muse, mutect2
- SLC4A7 | c.3295A>G p.I1099V | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99840288; called by muse, mutect2
- SLC7A8 | c.1360G>C p.A454P | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); catalogued as COSV100328576; called by muse, mutect2
- SOGA1 | c.2120C>G p.T707S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99415119; called by muse, mutect2
- SPATA20 | c.1051-1G>A p.X351_splice (on ENST00000356488 / NM_001258372.1; = p.X367_splice on NM_022827.4) | Splice Site (SNP) | VAF 24/70 reads (34%) | catalogued as COSV99136629; called by muse, mutect2, varscan2
- SPTBN2 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV100020372; called by muse, mutect2, varscan2
- SPTBN4 | c.3691G>A p.V1231M | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV100152015; called by muse, mutect2, varscan2
- ST3GAL3 | c.126T>A p.Y42* | Nonsense Mutation (SNP) | VAF 11/254 reads (4%) | catalogued as COSV99495975; called by muse, mutect2
- STAT4 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as COSV100636186; called by muse, mutect2
- SUPT5H | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 251/923 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV100782143, COSV63238583; called by muse, mutect2, varscan2
- SVEP1 | c.7435C>T p.L2479F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as COSV99929706; called by muse, mutect2, varscan2
- SYBU | c.737G>A p.R246H (on ENST00000276646 / NM_001099754.2; = p.R245H on NM_017786.6) | Missense Mutation (SNP) | VAF 40/852 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575944059, COSV52615037, COSV52621483; called by muse, mutect2
- SYK | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1352135646, COSV101002613; called by muse, mutect2
- SYN3 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.941); catalogued as COSV100249909; called by muse, mutect2, varscan2
- SYTL2 | c.1778C>T p.P593L (on ENST00000528231 / NM_001162951.2; = p.P1882L on NM_206927.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/666 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as rs773149753, COSV60356424; called by muse, mutect2, varscan2
- SYVN1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV99589270; called by muse, mutect2, varscan2
- TANC2 | c.1790del p.L597Wfs*4 | Frame Shift Del (DEL) | VAF 110/578 reads (19%) | catalogued as rs1284876631; called by mutect2, varscan2
- TCHP | c.877C>T p.L293= | Splice Region (SNP) | VAF 11/211 reads (5%) | catalogued as COSV100452640; called by muse, mutect2
- TGIF1 | c.72G>T p.K24N (on ENST00000330513 / NM_001374396.1; = p.K44N on NM_003244.4) | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM083183, COSV100394969; called by muse, mutect2
- TGM2 | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100821741; called by muse, mutect2
- TGM7 | c.1237C>A p.Q413K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101476896; called by muse, mutect2
- THOC1 | c.1870G>T p.E624* | Nonsense Mutation (SNP) | VAF 28/353 reads (8%) | catalogued as COSV99863603; called by muse, mutect2
- TIAF1 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.693); catalogued as COSV100572674; called by muse, mutect2, varscan2
- TLE4 | c.1427G>C p.R476P | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99512275, COSV99513044; called by muse, mutect2
- TMEM179B | c.387C>A p.C129* | Nonsense Mutation (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99585447; called by muse, mutect2
- TMEM74 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV52464250; called by muse, mutect2
- TRAF3IP2 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV100389881, COSV100389930; called by muse, mutect2
- TRIM10 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.249); catalogued as COSV100938905; called by muse, mutect2
- TRPM4 | c.3131G>A p.S1044N | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99420836; called by muse, mutect2
- TRPS1 | c.3026C>A p.S1009* (on ENST00000220888 / NM_001330599.2; = p.S1022* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/276 reads (5%) | catalogued as COSV99634028; called by muse, mutect2
- TRPV5 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 10/251 reads (4%) | catalogued as rs762806939, COSV99520625; called by muse, mutect2
- TSHZ3 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53681313; called by muse, mutect2
- TSPAN5 | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99995816; called by muse, mutect2
- TTLL3 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 70/921 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.08); catalogued as rs374967773; called by muse, mutect2
- TTN | c.58421G>A p.G19474D (on ENST00000591111; = p.G12050D on NM_003319.4) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | PolyPhen probably damaging (0.959); catalogued as COSV100625299, COSV59979729; called by muse, mutect2
- TXNIP | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 79/604 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV100997330; called by muse, mutect2, varscan2
- UBAP2L | c.595T>C p.F199L | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV99672223; called by muse, mutect2, varscan2
- UBE2L6 | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 21/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761956; called by muse, mutect2
- UBR4 | c.13289G>A p.C4430Y | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100921723; called by muse, mutect2
- UBTF | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 47/428 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV100256116; called by muse, mutect2, varscan2
- UGP2 | c.58T>C p.F20L | Missense Mutation (SNP) | VAF 18/517 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100451748; called by muse, mutect2
- UGT2B4 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 34/720 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100522623; called by muse, mutect2
- USP35 | c.2359T>A p.S787T | Missense Mutation (SNP) | VAF 60/610 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101489133; called by muse, mutect2
- VARS2 | c.2027T>A p.V676E | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV100423061; called by muse, mutect2, varscan2
- VARS2 | c.2140G>C p.G714R | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100423062; called by muse, mutect2, varscan2
- VDAC1 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV99198357; called by muse, mutect2, varscan2
- VPS13B | c.3974G>T p.W1325L | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100663431; called by muse, mutect2
- VPS13D | c.12200C>A p.S4067* | Nonsense Mutation (SNP) | VAF 18/262 reads (7%) | catalogued as COSV99169299; called by muse, mutect2
- VPS26B | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1443067262, COSV99845237; called by muse, mutect2, varscan2
- VPS4A | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99652125; called by muse, mutect2
- VTN | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV99879820; called by muse, mutect2, varscan2
- VWA8 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99865021; called by muse, mutect2
- WIZ | c.4300G>T p.G1434W (on ENST00000673675 / NM_001371589.1; = p.G339W on NM_021241.3) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99653726; called by muse, mutect2, varscan2
- WNT11 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490446; called by muse, mutect2, varscan2
- XKRX | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100139810; called by muse, mutect2
- XRCC6 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV100777907; called by muse, mutect2
- XYLT1 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 57/863 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763191; called by muse, mutect2
- ZBTB22 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV56470393, COSV99802615; called by muse, mutect2
- ZBTB39 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1004209507, COSV100268194; called by muse, varscan2
- ZNF132 | c.1512G>C p.Q504H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV99571334; called by muse, mutect2
- ZNF250 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs199528681, COSV52969886; called by muse, mutect2, varscan2
- ZNF395 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV100734068; called by muse, mutect2
- ZNF624 | c.2557G>A p.V853I | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV100257430; called by muse, mutect2
- ZNF687 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV55016471; called by muse, mutect2, varscan2
- ZNF711 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52151091; called by muse, mutect2
- ZNF875 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs755794469, COSV60990367; called by mutect2, varscan2
- ZNRF4 | c.1043G>A p.C348Y | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55776110, COSV99706700; called by muse, mutect2, varscan2
- ZSWIM5 | c.959C>G p.P320R | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100655782; called by muse, mutect2
- ADAT1 | c.1143_1160delinsAAAAGCTGATA p.A382Kfs*63 | Frame Shift Del (DEL) | VAF 31/195 reads (16%) | called by pindel, varscan2*
- ADCY10 | c.2147G>A p.S716N | Missense Mutation (SNP) | VAF 20/708 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2
- AK9 | c.3407dup p.L1136Ffs*17 | Frame Shift Ins (INS) | VAF 13/113 reads (12%) | called by mutect2, pindel, varscan2
- ANXA11 | c.680T>A p.L227Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ASAH2 | c.894-1G>A p.X298_splice | Splice Site (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- AXL | c.465dup p.F156Lfs*54 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- CALCB | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.04); called by muse, mutect2
- CD47 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- CHD6 | c.7181dup p.L2396Ifs*36 | Frame Shift Ins (INS) | VAF 16/149 reads (11%) | called by mutect2, pindel, varscan2
- CHMP1B | c.72del p.K24Nfs*40 | Frame Shift Del (DEL) | VAF 28/149 reads (19%) | called by mutect2, pindel, varscan2
- CNNM2 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- COL4A5 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COX18 | c.973T>A p.F325I | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.282); called by muse, mutect2
- DBNL | c.139+1dup | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- DGKG | c.520G>T p.G174W | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DHX30 | c.1483T>A p.S495T (on ENST00000445061 / NM_138615.3; = p.S456T on NM_014966.3) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- DYNLRB1 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2
- ENO3 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); called by muse, mutect2
- ENTPD5 | c.383del p.K128Rfs*21 | Frame Shift Del (DEL) | VAF 58/478 reads (12%) | called by mutect2, pindel, varscan2
- FMNL3 | c.2188A>T p.M730L | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.743); called by muse, mutect2
- GIGYF2 | c.2310_2311insTAGGACGGGTCCGG p.R771* | Nonsense Mutation (INS) | VAF 338/1490 reads (23%) | called by pindel, varscan2
- GPR179 | c.5254C>T p.P1752S (on ENST00000621958; = p.P1751S on NM_001004334.4) | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.233); called by muse, mutect2
- GPR179 | c.3701T>C p.L1234P (on ENST00000621958; = p.L1233P on NM_001004334.4) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GRID1 | c.1193G>C p.G398A | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- GRK4 | c.1255T>C p.S419P (on ENST00000398052 / NM_182982.3; = p.S387P on NM_005307.3) | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- GTF3C2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.1); called by muse, mutect2
- HYAL1 | c.570dup p.R191Afs*16 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- IGKC | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2
- IL15RA | c.707T>A p.L236Q | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.025); called by muse, mutect2
- ITPR2 | c.501G>T p.W167C | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- KCNA2 | c.633dup p.Y212Vfs*25 | Frame Shift Ins (INS) | VAF 6/72 reads (8%) | called by mutect2, pindel
- KIAA1217 | c.4464T>A p.N1488K | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2
- LAMA3 | c.7761A>T p.E2587D (on ENST00000313654 / NM_198129.4; = p.E978D on NM_000227.6) | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); called by muse, mutect2
- LRCH4 | c.1283dup p.R429Efs*4 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- LRCH4 | c.849-3dup | Splice Region (INS) | VAF 14/137 reads (10%) | called by pindel, varscan2
- LRIF1 | c.2044_2045insAAGGAGGGTCCC p.T682delinsKGGSP | In Frame Ins (INS) | VAF 282/750 reads (38%) | called by mutect2, pindel*, varscan2*
- LRRC6 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MARCHF2 | c.390del p.P131Rfs*86 | Frame Shift Del (DEL) | VAF 15/126 reads (12%) | called by mutect2, pindel, varscan2
- MDC1 | c.400del p.D134Mfs*12 | Frame Shift Del (DEL) | VAF 20/179 reads (11%) | called by mutect2, pindel, varscan2
- MICAL2 | c.518T>A p.L173Q | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC16 | c.15322T>C p.S5108P | Missense Mutation (SNP) | VAF 23/892 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- MYG1 | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 18/239 reads (8%) | called by muse, mutect2
- MYO5C | c.4189G>C p.A1397P | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEURL4 | c.4421dup p.P1475Sfs*60 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- NLGN4Y | c.763dup p.A255Gfs*132 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by pindel, varscan2
- NOS1AP | c.302G>A p.W101* | Nonsense Mutation (SNP) | VAF 22/502 reads (4%) | called by muse, mutect2
- NOXRED1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NXPH3 | c.452_453del p.P151Qfs*2 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel
- OS9 | c.713G>C p.S238T | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.977); called by muse, mutect2
- OXSR1 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 15/489 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- PAN2 | c.1994G>A p.S665N | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.097); called by muse, mutect2
- PCDH15 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA2 | c.1270del p.V424Wfs*2 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- PDE1B | c.709T>C p.C237R | Missense Mutation (SNP) | VAF 60/1178 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, mutect2
- PRKX | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2
- PTCH2 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- RNASE2 | c.161T>A p.M54K | Missense Mutation (SNP) | VAF 12/321 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- S1PR4 | c.595dup p.L199Pfs*240 | Frame Shift Ins (INS) | VAF 30/191 reads (16%) | called by mutect2, pindel, varscan2
- SETD2 | c.6032_6036dup p.L2013Nfs*9 | Frame Shift Ins (INS) | VAF 98/248 reads (40%) | called by pindel, varscan2
- SETD2 | c.6030_6031insTA p.K2011* | Frame Shift Ins (INS) | VAF 138/274 reads (50%) | called by muse*, mutect2, varscan2*
- SFXN1 | c.625del p.D209Mfs*40 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- SLC17A3 | c.887del p.L296* | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by mutect2, varscan2
- SLIT3 | c.3177-1G>T p.X1059_splice | Splice Site (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- SPON1 | c.1835C>T p.T612I | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.273); called by muse, mutect2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 44/216 reads (20%) | called by mutect2, pindel, varscan2
- SYT3 | c.578dup p.A194Sfs*54 | Frame Shift Ins (INS) | VAF 16/141 reads (11%) | called by mutect2, pindel, varscan2
- TACC2 | c.6683dup p.V2229Cfs*22 (on ENST00000334433; = p.V307Cfs*22 on NM_006997.4) | Frame Shift Ins (INS) | VAF 16/105 reads (15%) | called by mutect2, varscan2
- TBL1X | c.845dup p.H283Pfs*2 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- TOMM34 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 19/596 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2
- TRAJ37 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- TRMT5 | c.1366G>C p.A456P | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRPM8 | c.368A>T p.D123V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2
- TTC4 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2
- TTC6 | c.1000G>A p.A334T (on ENST00000267368; = p.A1700T on NM_001310135.3) | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP8 | c.929A>C p.Q310P | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); called by muse, mutect2
- WASHC2A | c.3440G>T p.R1147I | Missense Mutation (SNP) | VAF 14/303 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2
- WDR73 | c.701del p.G234Afs*29 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- WDSUB1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ZDHHC3 | c.761dup p.E255Gfs*7 (on ENST00000424952 / NM_001135179.2; = p.E283Gfs*7 on NM_016598.3) | Frame Shift Ins (INS) | VAF 21/147 reads (14%) | called by mutect2, pindel, varscan2
- ZNF460 | c.1471C>T p.L491F | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.94); called by muse, mutect2
- ZNF683 | c.1558del p.Q520Rfs*? (on ENST00000403843; = p.Q500Rfs*? on NM_173574.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/266 reads (14%) | called by pindel, varscan2
- ZNF695 | c.530G>C p.S177T | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.108); called by muse, mutect2
- ABCB11 | c.2859T>C p.I953= | Silent (SNP) | VAF 65/1060 reads (6%) | catalogued as COSV99792923; called by muse, mutect2
- ACSF3 | c.900G>A p.L300= | Silent (SNP) | VAF 38/1015 reads (4%) | catalogued as COSV100441542; called by muse, mutect2
- ADCY3 | c.1539G>A p.L513= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99569053; called by muse, mutect2, varscan2
- AKAP6 | c.444G>A p.Q148= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as COSV99804127; called by muse, mutect2
- ANGPTL4 | c.1170G>A p.L390= | Silent (SNP) | VAF 44/155 reads (28%) | catalogued as COSV100035069; called by muse, mutect2, varscan2
- AP1M2 | c.1146C>A p.I382= | Silent (SNP) | VAF 20/259 reads (8%) | catalogued as rs200574564, COSV51569433, COSV99141007; called by muse, mutect2
- APEH | c.756C>T p.A252= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99611101; called by muse, mutect2, varscan2
- ARHGAP4 | c.732C>T p.N244= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs782801557, COSV100604220; called by muse, mutect2, varscan2
- AVIL | c.1383G>A p.V461= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV99142599; called by muse, mutect2, varscan2
- C1QTNF4 | c.732G>A p.S244= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100209390; called by muse, mutect2, varscan2
- C2CD3 | c.4590G>A p.T1530= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as rs200072798, COSV100487349; called by muse, mutect2, varscan2
- CA6 | c.739C>T p.L247= | Silent (SNP) | VAF 63/740 reads (9%) | catalogued as COSV101077675; called by muse, mutect2
- CD5L | c.429C>T p.G143= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- CDH22 | c.276G>A p.E92= | Silent (SNP) | VAF 44/185 reads (24%) | catalogued as COSV100952976; called by muse, mutect2, varscan2
- CDH8 | c.2367C>T p.L789= | Silent (SNP) | VAF 845/945 reads (89%) | catalogued as COSV100183961, COSV54868623; called by muse, mutect2, varscan2
- CEACAM18 | c.180C>T p.S60= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as COSV101140669; called by muse, mutect2
- CEACAM8 | c.577C>T p.L193= | Silent (SNP) | VAF 36/946 reads (4%) | catalogued as COSV99747840; called by muse, mutect2
- CGB7 | c.34C>T p.L12= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs761497277, COSV100655118; called by mutect2, varscan2
- CHD3 | c.3339C>A p.A1113= | Silent (SNP) | VAF 115/420 reads (27%) | catalogued as COSV100391633; called by muse, varscan2
- CHD6 | c.6975C>T p.S2325= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs569449242, COSV100951347; called by muse, mutect2
- CHM | c.546T>C p.C182= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as COSV100753614; called by muse, mutect2
- CKMT2 | c.36C>T p.R12= | Silent (SNP) | VAF 26/287 reads (9%) | catalogued as COSV99562483; called by muse, mutect2
- CNR2 | c.138A>G p.L46= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as rs1350755540, COSV100991583; called by muse, mutect2
- COL4A6 | c.4833C>A p.A1611= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV100564962; called by muse, mutect2, varscan2
- COL8A2 | c.1854C>T p.G618= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs768247177, COSV100291372; called by mutect2, varscan2
- CTNNA1 | c.462G>T p.L154= | Silent (SNP) | VAF 17/175 reads (10%) | catalogued as COSV100243228; called by muse, mutect2, varscan2
- CUL9 | c.2535C>T p.S845= | Silent (SNP) | VAF 27/303 reads (9%) | catalogued as rs774565346, COSV99335998; called by muse, mutect2
- DCST2 | c.96G>T p.L32= | Silent (SNP) | VAF 23/188 reads (12%) | catalogued as COSV99792228; called by muse, mutect2, varscan2
- DSE | c.2286C>A p.S762= | Silent (SNP) | VAF 11/169 reads (7%) | catalogued as COSV100528785; called by muse, mutect2
- DZIP1L | c.1737C>T p.S579= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs1434335240, COSV100551682; called by muse, mutect2
- EBF1 | c.84G>C p.R28= | Silent (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- EGR1 | c.1242T>C p.H414= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV99525586; called by muse, mutect2
- EGR3 | c.294C>T p.C98= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs770564582, COSV100416268; called by muse, mutect2, varscan2
- EIF1AD | c.444C>T p.N148= | Silent (SNP) | VAF 30/794 reads (4%) | catalogued as COSV100381417; called by muse, mutect2
- ERCC2 | c.390C>T p.V130= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs757159764, COSV99676493; called by muse, mutect2, varscan2
- ERICH6 | c.1759C>A p.R587= | Silent (SNP) | VAF 63/554 reads (11%) | catalogued as COSV99901956; called by muse, mutect2, varscan2
- FAAP24 | c.492G>A p.Q164= | Silent (SNP) | VAF 20/490 reads (4%) | catalogued as COSV99578244; called by muse, mutect2
- FABP3 | c.267A>G p.G89= | Silent (SNP) | VAF 29/638 reads (5%) | called by muse, mutect2
- FAM204A | c.519C>A p.L173= | Silent (SNP) | VAF 19/356 reads (5%) | catalogued as COSV100977452; called by muse, mutect2
- FAM78B | c.633G>A p.L211= | Silent (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- FBP2 | c.499C>T p.L167= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV64694736; called by muse, mutect2
- FER1L6 | c.4632G>A p.R1544= | Silent (SNP) | VAF 18/359 reads (5%) | catalogued as COSV67551057; called by muse, mutect2
- FLG | c.4176T>A p.G1392= | Silent (SNP) | VAF 12/234 reads (5%) | catalogued as COSV100912084; called by muse, mutect2
- FTSJ3 | c.753T>C p.R251= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as rs1199298373, COSV100037440; called by muse, mutect2, varscan2
- G6PC3 | c.711G>A p.R237= | Silent (SNP) | VAF 33/201 reads (16%) | catalogued as COSV99291364; called by muse, mutect2, varscan2
- GCM1 | c.1212A>T p.P404= | Silent (SNP) | VAF 25/942 reads (3%) | catalogued as COSV99452631; called by muse, mutect2
- GDPD3 | c.453C>T p.I151= | Silent (SNP) | VAF 12/358 reads (3%) | called by muse, mutect2
- GIMAP4 | c.390G>A p.E130= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as COSV99751105; called by muse, mutect2
- GJA10 | c.1401C>G p.P467= | Silent (SNP) | VAF 24/404 reads (6%) | catalogued as COSV101005438; called by muse, mutect2
- GPR137 | c.861C>T p.P287= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100464470; called by muse, mutect2, varscan2
- GSTA4 | c.225A>C p.I75= | Silent (SNP) | VAF 24/243 reads (10%) | catalogued as COSV100919901; called by muse, mutect2, varscan2
- HECTD4 | c.8524C>T p.L2842= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV101108349; called by muse, mutect2
- IFITM3 | c.189C>T p.F63= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV101296805; called by muse, mutect2, varscan2
- IGLV2-14 | c.327C>T p.C109= | Silent (SNP) | VAF 12/306 reads (4%) | catalogued as rs1466696889; called by muse, mutect2
- ITGB1BP1 | c.69C>T p.S23= | Silent (SNP) | VAF 12/274 reads (4%) | catalogued as COSV99432169; called by muse, mutect2
- KAT2A | c.531G>T p.V177= | Silent (SNP) | VAF 12/197 reads (6%) | catalogued as COSV56790852; called by muse, mutect2
- KCTD19 | c.477G>A p.G159= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100431201; called by muse, mutect2
- KRTAP5-9 | c.372C>A p.S124= | Silent (SNP) | VAF 28/602 reads (5%) | catalogued as COSV101603643; called by muse, mutect2
- L3MBTL3 | c.1833T>C p.F611= | Silent (SNP) | VAF 18/326 reads (6%) | catalogued as COSV100696376; called by muse, mutect2
- LIPC | c.60A>G p.S20= | Silent (SNP) | VAF 9/137 reads (7%) | catalogued as COSV100134844; called by muse, mutect2
- LMBR1L | c.850C>T p.L284= | Silent (SNP) | VAF 46/476 reads (10%) | catalogued as COSV99918976; called by muse, mutect2
- LOX | c.843A>G p.R281= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99140712; called by muse, mutect2, varscan2
- LPAR1 | c.690C>T p.G230= | Silent (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- MAP11 | c.1713C>T p.C571= | Silent (SNP) | VAF 12/298 reads (4%) | catalogued as COSV100385625; called by muse, mutect2
- MEGF8 | c.3666C>T p.G1222= (on ENST00000251268 / NM_001271938.2; = p.G1155= on NM_001410.3) | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99238824; called by muse, mutect2
- MGAT2 | c.804T>C p.F268= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV100023632; called by muse, mutect2
- MICAL1 | c.1725G>C p.V575= | Silent (SNP) | VAF 40/238 reads (17%) | catalogued as COSV99238149; called by muse, mutect2, varscan2
- NABP2 | c.222C>T p.Y74= | Silent (SNP) | VAF 26/428 reads (6%) | catalogued as rs754910573, COSV99910416; called by muse, mutect2
- NCKAP5 | c.2592C>T p.H864= | Silent (SNP) | VAF 34/406 reads (8%) | catalogued as COSV100494200, COSV58428691; called by muse, mutect2
- NEB | c.14061G>T p.V4687= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as COSV99427445; called by muse, mutect2
- NFE2L2 | c.768C>T p.S256= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as COSV101229435; called by muse, mutect2
- NSG1 | c.558G>A p.*186= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100086400, COSV100086422; called by muse, mutect2
- NUMBL | c.951G>A p.S317= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as rs1485300156; called by muse, mutect2
- OPHN1 | c.1434G>A p.L478= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV100830742; called by muse, mutect2, varscan2
- OR3A2 | c.723G>A p.E241= | Silent (SNP) | VAF 14/242 reads (6%) | catalogued as COSV68695164; called by muse, mutect2
- OR7G3 | c.118C>T p.L40= | Silent (SNP) | VAF 59/586 reads (10%) | catalogued as COSV100555748; called by muse, mutect2, varscan2
- PCSK5 | c.1890G>A p.E630= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as COSV65095667, COSV65096382; called by muse, mutect2
- PLEKHA5 | c.594C>T p.C198= | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as COSV100164704; called by muse, mutect2
- PLEKHG1 | c.2892G>A p.L964= | Silent (SNP) | VAF 24/529 reads (5%) | catalogued as COSV100651866; called by muse, mutect2
- PLEKHM2 | c.471C>A p.A157= | Silent (SNP) | VAF 15/230 reads (7%) | catalogued as COSV101009196; called by muse, mutect2
- PLXNA2 | c.3630C>T p.H1210= | Silent (SNP) | VAF 14/149 reads (9%) | catalogued as rs543030636, COSV100885649, COSV100885836; called by muse, varscan2
- PNPLA8 | c.1785A>G p.G595= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99993782; called by muse, mutect2
- POLR3A | c.1305A>G p.G435= | Silent (SNP) | VAF 22/379 reads (6%) | catalogued as COSV100965791; called by muse, mutect2
- POU5F1 | c.495C>G p.A165= | Silent (SNP) | VAF 61/180 reads (34%) | catalogued as COSV52564984, COSV99463256; called by muse, mutect2, varscan2
- PRKCE | c.741C>A p.I247= | Silent (SNP) | VAF 92/376 reads (24%) | catalogued as COSV100077431; called by mutect2, varscan2
- PSMD10 | c.130T>C p.L44= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV54264343; called by muse, mutect2
- PSMD4 | c.570T>C p.A190= | Silent (SNP) | VAF 15/335 reads (4%) | catalogued as COSV100924693; called by muse, mutect2
- PTCHD4 | c.2424G>A p.T808= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs1399343562, COSV59781073; called by muse, mutect2
- QTRT1 | c.879G>T p.L293= | Silent (SNP) | VAF 31/437 reads (7%) | catalogued as COSV99139105; called by muse, mutect2
- RCC2 | c.420C>T p.H140= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100965196; called by muse, mutect2
- REG3A | c.21G>A p.L7= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100532910, COSV59412536; called by muse, mutect2
- RFWD3 | c.1791T>C p.A597= | Silent (SNP) | VAF 23/435 reads (5%) | catalogued as COSV100736314; called by muse, mutect2
- RGL1 | c.1395C>T p.C465= (on ENST00000360851 / NM_001297672.2; = p.C500= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/512 reads (6%) | catalogued as rs1210011185, COSV100487633; called by muse, mutect2
- RNF168 | c.603C>T p.S201= | Silent (SNP) | VAF 18/456 reads (4%) | called by muse, mutect2
- RNF183 | c.277C>T p.L93= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as rs1457734532; called by muse, mutect2
- RUNDC1 | c.1251A>G p.G417= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV64512547; called by muse, mutect2
- RUSC2 | c.378C>A p.A126= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV100770867; called by muse, mutect2, varscan2
- SCRIB | c.1680C>G p.A560= | Silent (SNP) | VAF 35/54 reads (65%) | catalogued as COSV57582286, COSV57585066; called by muse, mutect2, varscan2
- SCTR | c.1095T>C p.A365= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV99191720; called by muse, mutect2, varscan2
- SDK2 | c.6174C>T p.D2058= | Silent (SNP) | VAF 14/354 reads (4%) | called by muse, mutect2
- SERPIND1 | c.1350C>A p.T450= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as COSV99300449; called by muse, mutect2
- SIRPB2 | c.441G>A p.V147= | Silent (SNP) | VAF 32/1236 reads (3%) | catalogued as COSV100708623; called by muse, mutect2
- SLC35F4 | c.78T>A p.G26= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- SLC39A7 | c.132C>T p.G44= | Silent (SNP) | VAF 24/215 reads (11%) | catalogued as COSV100807851; called by muse, mutect2, varscan2
- SLC5A5 | c.1008G>A p.L336= | Silent (SNP) | VAF 10/256 reads (4%) | catalogued as rs1214952590, COSV99715360; called by muse, mutect2
- SLITRK1 | c.1842G>A p.R614= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1173357558, COSV101000051; called by muse, mutect2
- SMUG1 | c.21G>A p.L7= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1168711580, COSV99679533; called by muse, mutect2, varscan2
- SNX10 | c.178C>T p.L60= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs747414477, COSV100640136; called by muse, mutect2, varscan2
- SPATA5 | c.1587G>A p.R529= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV99916304; called by muse, mutect2
- SPTBN1 | c.3393G>A p.G1131= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as rs1383229699, COSV100443350, COSV61691561; called by muse, mutect2, varscan2
- SREBF2 | c.372A>G p.T124= | Silent (SNP) | VAF 26/514 reads (5%) | catalogued as COSV100761543; called by muse, mutect2
- TAAR8 | c.184C>T p.L62= | Silent (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- TBX4 | c.1362G>A p.R454= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV99540643; called by muse, mutect2, varscan2
- TIE1 | c.648G>A p.G216= | Silent (SNP) | VAF 17/250 reads (7%) | catalogued as COSV100992170; called by muse, mutect2
- TIGD3 | c.561C>T p.G187= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99361923; called by muse, mutect2, varscan2
- TM4SF20 | c.228G>A p.A76= | Silent (SNP) | VAF 45/1000 reads (5%) | catalogued as rs138547735, COSV58818608; called by muse, mutect2
- TMEM43 | c.132G>A p.L44= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs770765460; called by mutect2, varscan2
- TNRC18 | c.6909C>A p.R2303= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100079112; called by muse, mutect2, varscan2
- TNXB | c.4980C>A p.P1660= (on ENST00000647633; = p.P1413= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 128/627 reads (20%) | catalogued as COSV64484504; called by muse, mutect2, varscan2
- TRMT1L | c.2160A>G p.S720= | Silent (SNP) | VAF 17/280 reads (6%) | catalogued as COSV100834741; called by muse, mutect2
- USP35 | c.966C>T p.V322= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV101489132; called by muse, mutect2, varscan2
- ZBTB39 | c.49C>T p.L17= | Silent (SNP) | VAF 12/209 reads (6%) | catalogued as COSV100268197; called by muse, mutect2
- ZKSCAN1 | c.1134A>G p.R378= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as COSV100164352; called by muse, mutect2
- ZNF135 | c.1362C>T p.S454= (on ENST00000313434 / NM_001289401.2; = p.S466= on NM_003436.4) | Silent (SNP) | VAF 11/348 reads (3%) | called by muse, mutect2
- ZNF274 | c.1872T>C p.C624= (on ENST00000610905; = p.C519= on NM_016324.3) | Silent (SNP) | VAF 14/259 reads (5%) | catalogued as COSV100465452; called by muse, mutect2
- ZNF568 | c.1074G>A p.G358= | Silent (SNP) | VAF 16/235 reads (7%) | catalogued as COSV100451426; called by muse, mutect2
- ZNF74 | c.921C>T p.G307= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1037455539, COSV62621269; called by muse, mutect2, varscan2
- ANKS1B | c.2420-53C>T | Intron (SNP) | VAF 47/397 reads (12%) | catalogued as COSV100228805; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504883 C>A | 5'Flank (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- CTPS2 | c.1393+200G>A | Intron (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- DNPH1 | c.376+28T>A | Intron (SNP) | VAF 9/178 reads (5%) | catalogued as COSV99335999; called by muse, mutect2
- FBXL18 | c.2000+1048A>G | Intron (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101212105; called by muse, mutect2
- LINC01588 | n.792C>A | RNA (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- MAX | c.172-6179T>C | Intron (SNP) | VAF 13/331 reads (4%) | called by muse, mutect2
- METTL16 | chr17:2415219 G>A | 3'Flank (SNP) | VAF 17/316 reads (5%) | called by muse, mutect2
- PIK3C2B | c.934-1522C>T | Intron (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- RPP38 | chr10:15096733 G>A | 5'Flank (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- RPS8 | c.112-109G>A | Intron (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- RUSC1 | c.-87+20T>G | Intron (SNP) | VAF 10/130 reads (8%) | catalogued as COSV99430230; called by muse, mutect2
- TSR1 | c.1903+202G>A | Intron (SNP) | VAF 62/776 reads (8%) | catalogued as COSV100027205; called by muse, mutect2
- USH1C | c.1284+1132A>G | Intron (SNP) | VAF 4/53 reads (8%) | catalogued as COSV99141811; called by muse, mutect2
- VPS13D | c.13035+172G>C | Intron (SNP) | VAF 24/119 reads (20%) | catalogued as COSV99169300; called by muse, mutect2, varscan2
- ZMYND8 | c.3425-1812C>T | Intron (SNP) | VAF 16/116 reads (14%) | catalogued as COSV99521236; called by muse, mutect2, varscan2
- ZSCAN32 | c.839-638A>G | Intron (SNP) | VAF 12/377 reads (3%) | called by muse, mutect2
